Somatic mutation profile of cancer-model specimen HCM-WCMC-1074-C56-85A (3D Organoid; aliquot HCM-WCMC-1074-C56-85A-01D-A88H-36), derived from the primary tumor of HCMI case HCM-WCMC-1074-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Ovary; FIGO stage: Stage IC2; Age at diagnosis: 72.9 years (26,625 days).
Specimen HCM-WCMC-1074-C56-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 30837afe-11be-4670-b6aa-7a1521e25d06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-1074-C56-10A (Blood Derived Normal), aliquot HCM-WCMC-1074-C56-10A-01D-A88H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e02aba67-633c-4626-bfd5-2ffa7fa5ac39

The open-access MAF lists 41 somatic variants for this specimen: 27 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 12, Intron 2, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 133/301 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- C16orf91 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 133/693 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1187195544; called by muse, mutect2, varscan2
- GAL3ST4 | c.1420G>A p.V474I | Missense Mutation (SNP) | VAF 171/379 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.566); catalogued as rs745563991, COSV57585738; called by muse, mutect2, varscan2
- IL17RD | c.1718G>A p.R573H | Missense Mutation (SNP) | VAF 74/476 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs776344177, COSV56335407, COSV56343092; called by muse, mutect2, varscan2
- KANK4 | c.2044G>A p.G682S | Missense Mutation (SNP) | VAF 174/355 reads (49%) | SIFT tolerated (0.51); PolyPhen benign (0.013); catalogued as rs140407819; called by muse, mutect2, varscan2
- KEAP1 | c.1091G>A p.G364D | Missense Mutation (SNP) | VAF 18/522 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV50646098; called by muse, mutect2
- NPR2 | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 519/777 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.268); catalogued as rs768101143; called by muse, mutect2, varscan2
- PRDM14 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 193/428 reads (45%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.738); catalogued as rs576020321, COSV52570385, COSV52570815; called by muse, mutect2, varscan2
- R3HCC1L | c.1738A>G p.M580V | Missense Mutation (SNP) | VAF 84/203 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as rs752506296, COSV54401349; called by muse, mutect2, varscan2
- RPL5 | c.795-1G>C p.X265_splice | Splice Site (SNP) | VAF 62/160 reads (39%) | catalogued as COSV59873287; called by muse, varscan2
- SETD5 | c.2416C>A p.Q806K | Missense Mutation (SNP) | VAF 113/230 reads (49%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.446); catalogued as COSV56712056; called by muse, mutect2, varscan2
- SYT3 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 142/324 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs757705902, COSV58895405, COSV58897241, COSV58898207; called by muse, mutect2
- TAF1L | c.3731G>A p.R1244Q | Missense Mutation (SNP) | VAF 238/768 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs371427336; called by muse, mutect2, varscan2
- UPB1 | c.888C>A p.N296K | Missense Mutation (SNP) | VAF 95/334 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as rs529059518; called by muse, mutect2, varscan2
- ADAMTS12 | c.2510G>T p.S837I | Missense Mutation (SNP) | VAF 139/272 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ADGRA3 | c.942T>G p.I314M | Missense Mutation (SNP) | VAF 94/207 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- DNAH11 | c.8708C>T p.A2903V | Missense Mutation (SNP) | VAF 149/336 reads (44%) | SIFT tolerated (1); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- GPR161 | c.529A>T p.M177L | Missense Mutation (SNP) | VAF 288/585 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- H4C12 | c.256G>T p.D86Y | Missense Mutation (SNP) | VAF 171/423 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HIPK3 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 169/332 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PIEZO2 | c.4234A>T p.I1412F | Missense Mutation (SNP) | VAF 174/391 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- RHBDD3 | c.107G>T p.G36V | Missense Mutation (SNP) | VAF 63/694 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.051); called by muse, mutect2
- RXFP2 | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 96/208 reads (46%) | called by muse, mutect2, varscan2
- SPATS1 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 147/331 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- TCF24 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 341/749 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF462 | c.3167A>T p.E1056V | Missense Mutation (SNP) | VAF 203/431 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ZNF470 | c.1628G>T p.G543V | Missense Mutation (SNP) | VAF 175/377 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- CFAP47 | c.8031A>T p.V2677= | Silent (SNP) | VAF 105/202 reads (52%) | called by muse, mutect2, varscan2
- COL5A1 | c.4158G>A p.S1386= | Silent (SNP) | VAF 213/449 reads (47%) | catalogued as rs1383677988; ClinVar: likely benign; called by muse, mutect2, varscan2
- IRX1 | c.201G>A p.A67= | Silent (SNP) | VAF 214/444 reads (48%) | catalogued as rs767522817, COSV57357712, COSV57363223; called by muse, mutect2, varscan2
- LRRC8A | c.330C>T p.D110= | Silent (SNP) | VAF 226/520 reads (43%) | catalogued as rs201405629, COSV52189377; called by muse, mutect2, varscan2
- PNPLA3 | c.634C>T p.L212= | Silent (SNP) | VAF 206/395 reads (52%) | catalogued as COSV53377536; called by muse, varscan2
- PRRC2B | c.1203G>A p.R401= | Silent (SNP) | VAF 122/263 reads (46%) | catalogued as rs1161939796; called by muse, mutect2, varscan2
- PXDN | c.1060C>T p.L354= | Silent (SNP) | VAF 206/438 reads (47%) | called by muse, varscan2
- SLCO1B1 | c.366G>A p.R122= | Silent (SNP) | VAF 54/105 reads (51%) | catalogued as rs756788386; called by muse, varscan2
- SP3 | c.1893C>G p.V631= | Silent (SNP) | VAF 163/331 reads (49%) | catalogued as COSV59467079; called by muse, mutect2, varscan2
- TBC1D12 | c.567C>G p.S189= | Silent (SNP) | VAF 321/641 reads (50%) | catalogued as rs1007911226; called by muse, mutect2, varscan2
- TPO | c.444G>A p.A148= | Silent (SNP) | VAF 196/386 reads (51%) | catalogued as rs376413622; called by muse, mutect2, varscan2
- TTC30A | c.1951A>C p.R651= | Silent (SNP) | VAF 96/216 reads (44%) | catalogued as rs1335691800; called by muse, mutect2, varscan2
- IGFN1 | c.1241+2580T>C | Intron (SNP) | VAF 218/452 reads (48%) | catalogued as rs1347999943; called by muse, mutect2, varscan2
- KCNQ1 | c.1394-28801T>C | Intron (SNP) | VAF 138/298 reads (46%) | called by muse, mutect2, varscan2
